Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040030-09A.4 (aliquot TARGET-15-SJMPAL040030-09A.4-01D) from TARGET case TARGET-15-SJMPAL040030, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,931 days).
Specimen TARGET-15-SJMPAL040030-09A.4: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6da6924-204b-45d2-9bd3-0fa59c9366ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040030-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040030-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd4777df-ea22-498f-a9c5-5184464f6bbd

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 49/248 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HMCN2 | c.13760C>T p.S4587L | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs1315283512, COSV56739966; called by muse, mutect2, varscan2
- HSBP1L1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs757201263, COSV54099598; called by muse, varscan2
- CCT8 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTNAP2 | c.3101A>G p.D1034G | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRP1 | c.7315C>T p.R2439W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MRPL39 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SCN8A | c.1145C>A p.A382E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2
- NECTIN3-AS1 | n.1172+59G>A | Intron (SNP) | VAF 14/49 reads (29%) | catalogued as rs1429250420; called by muse, mutect2, varscan2
